Somatic mutation profile of tumor specimen TCGA-E1-A7YV-01A (aliquot TCGA-E1-A7YV-01A-11D-A34J-08) from TCGA case TCGA-E1-A7YV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 26.1 years (9,546 days).
Specimen TCGA-E1-A7YV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b17c244e-2a38-4d7d-b303-8898bf51ced7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-A7YV-10A (Blood Derived Normal), aliquot TCGA-E1-A7YV-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89c8e5f4-dcd6-4bc1-9c7a-1c8cd4b2a632

The open-access MAF lists 48 somatic variants for this specimen: 32 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 24, Silent 16, Frame Shift Del 5, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HCN1 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.788); catalogued as rs587777495, CM145438, COSV57542899; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/125 reads (29%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA5 | c.4271A>G p.E1424G | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.797); catalogued as COSV101201042; called by muse, mutect2, varscan2
- AFM | c.272A>T p.N91I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.108); catalogued as COSV99888630; called by muse, mutect2, varscan2
- AHCTF1 | c.5803A>G p.S1935G (on ENST00000366508; = p.S1909G on NM_015446.5) | Missense Mutation (SNP) | VAF 48/75 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100403349; called by muse, mutect2, varscan2
- ATRX | c.3146del p.I1049Kfs*69 | Frame Shift Del (DEL) | VAF 58/189 reads (31%) | catalogued as COSV64880556; called by mutect2, pindel, varscan2
- CCDC88A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759199436, COSV55061023, COSV99709972; called by muse, mutect2, varscan2
- CFAP46 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs536559191, COSV100886078; called by muse, mutect2, varscan2
- CSMD3 | c.1015A>G p.S339G | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.601); catalogued as COSV99828446; called by muse, mutect2
- FASTK | c.745C>T p.R249W | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1247251202, COSV52539178; called by muse, mutect2, varscan2
- GPR37 | c.1225G>A p.G409R | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.166); catalogued as COSV58259101, COSV58260050; called by muse, mutect2
- HBG2 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100400592, COSV100400758; called by muse, mutect2
- LMBRD1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs886061692, COSV65300356, COSV65300932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAOA | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.441); catalogued as COSV100108674; called by muse, mutect2, varscan2
- MEI1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100299734; called by muse, mutect2, varscan2
- NAPSA | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99515756; called by muse, mutect2
- OR10H5 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 19/105 reads (18%) | catalogued as COSV58278121; called by muse, mutect2, varscan2
- PAM | c.1069A>C p.M357L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV99173169; called by muse, mutect2, varscan2
- PEAK1 | c.1870A>G p.I624V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs1055519665, COSV100432643; called by muse, mutect2, varscan2
- QKI | c.401dup p.E135Gfs*5 | Frame Shift Ins (INS) | VAF 31/85 reads (36%) | catalogued as rs755727862; called by mutect2, varscan2
- ROS1 | c.5698A>G p.I1900V | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100876673; called by muse, mutect2, varscan2
- SCNN1G | c.65C>A p.A22E | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100264035, COSV55597342; called by muse, mutect2, varscan2
- SYCP2L | c.1542del p.S515Vfs*14 | Frame Shift Del (DEL) | VAF 28/84 reads (33%) | catalogued as COSV51650478; called by mutect2, pindel, varscan2
- TBL1XR1 | c.1232C>G p.A411G | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.099); catalogued as COSV101467729; called by muse, mutect2, varscan2
- TMEM185A | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100382962; called by muse, mutect2, varscan2
- TRANK1 | c.5303A>G p.K1768R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100081999; called by muse, mutect2, varscan2
- TRIML1 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs914391345, COSV100205810; called by muse, mutect2, varscan2
- UGT2B4 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV100522283; called by muse, mutect2, varscan2
- VIT | c.1560C>G p.N520K (on ENST00000389975 / NM_001177969.1; = p.N535K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007242; called by muse, mutect2, varscan2
- SPAG17 | c.4083_4084del p.Q1363Vfs*6 | Frame Shift Del (DEL) | VAF 27/84 reads (32%) | called by mutect2, pindel, varscan2
- TRAF2 | c.27del p.G10Afs*76 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | called by mutect2, pindel, varscan2
- TTN | c.83636del p.G27879Afs*27 (on ENST00000591111; = p.G20455Afs*27 on NM_003319.4) | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- AMELX | c.552G>A p.K184= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV100497454; called by muse, mutect2, varscan2
- CLTCL1 | c.4335G>T p.L1445= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV99594687; called by muse, mutect2, varscan2
- FAM83B | c.2217C>A p.S739= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV100174201, COSV100174227; called by muse, mutect2
- GOLGA3 | c.3441A>G p.A1147= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as COSV99202362; called by muse, mutect2
- GSDME | c.309G>T p.L103= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as COSV100742281, COSV61651836; called by muse, mutect2, varscan2
- HBG2 | c.411A>G p.G137= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV100400590, COSV57963605; called by muse, mutect2
- NEU3 | c.993T>A p.S331= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV99579216; called by muse, mutect2, varscan2
- PCDH11X | c.3252C>T p.G1084= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as COSV100009695; called by muse, mutect2, varscan2
- PLCB2 | c.363C>T p.N121= | Silent (SNP) | VAF 28/42 reads (67%) | catalogued as rs775985238, COSV53037482; called by muse, varscan2
- PNPLA6 | c.1767C>A p.G589= (on ENST00000414982 / NM_001166111.2; = p.G541= on NM_006702.5) | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV99653296; called by muse, mutect2, varscan2
- PRR22 | c.616C>T p.L206= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1321685156, COSV100288005; called by muse, mutect2, varscan2
- RIMS1 | c.528G>C p.G176= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1460836109, COSV99325083; called by muse, mutect2, varscan2
- SSC4D | c.117T>A p.L39= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99299855; called by muse, mutect2, varscan2
- TONSL | c.1188T>A p.I396= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101340172; called by muse, mutect2, varscan2
- UBE2NL | c.36C>A p.T12= | Silent (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- ZNF43 | c.1317A>T p.S439= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV100731734; called by muse, mutect2, varscan2
